Somatic mutation profile of tumor specimen TCGA-BF-A5ES-01A (aliquot TCGA-BF-A5ES-01A-11D-A27K-08) from TCGA case TCGA-BF-A5ES, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 76.9 years (28,092 days).
Specimen TCGA-BF-A5ES-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1e9f775-ac7c-4cf8-8dda-3bcfa0c19413.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-A5ES-10A (Blood Derived Normal), aliquot TCGA-BF-A5ES-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a608c9c-c567-4b8a-9522-251fcc67ca29

The open-access MAF lists 616 somatic variants for this specimen: 404 protein-altering or splice-affecting, 200 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 369, Silent 200, Nonsense Mutation 21, RNA 6, Splice Region 6, Frame Shift Del 5, Intron 4, Splice Site 2, 3'UTR 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMHR2 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs137853104, CM016199, COSV99143488; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F8 | c.6977G>A p.R2326Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852360, CD101348, CM012947, CM860009, CM890047, COSV100371798; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GYS2 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 24/57 reads (42%) | catalogued as rs267603422, COSV53921842; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIT | c.1727T>C p.L576P | Missense Mutation (SNP) | VAF 32/64 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs121913513, CM133722, COSV55386593, COSV55412340; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA12 | c.7187G>A p.R2396K (on ENST00000272895 / NM_173076.3; = p.R2078K on NM_015657.3) | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55960241; called by muse, mutect2, varscan2
- ABCC2 | c.1581C>A p.N527K | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV100966671; called by muse, mutect2, varscan2
- ABCC6 | c.1418G>A p.R473K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.094); catalogued as COSV99229466; called by muse, mutect2, varscan2
- ABHD16A | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101013335; called by muse, mutect2, varscan2
- ACACB | c.1426C>T p.L476F | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV100623232; called by muse, mutect2, varscan2
- ACAN | c.6269G>A p.G2090E | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.227); catalogued as COSV100719058, COSV61368114; called by muse, mutect2, varscan2
- ACOXL | c.1637G>A p.R546K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as COSV100929880; called by muse, mutect2, varscan2
- ACSM4 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV68068408; called by muse, mutect2
- ACTRT1 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 131/338 reads (39%) | catalogued as rs767426435, COSV100947568, COSV64419153; called by muse, mutect2, varscan2
- ACVR1C | c.748C>T p.L250F | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99694993; called by muse, mutect2, varscan2
- ADGRE2 | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.16); catalogued as COSV100216433; called by muse, mutect2, varscan2
- ADGRE5 | c.895C>T p.Q299* (on ENST00000242786 / NM_078481.4; = p.Q206* on NM_001784.5) | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as COSV99663192; called by muse, mutect2
- ADGRG2 | c.634C>T p.R212* (on ENST00000379869 / NM_001079858.3; = p.R209* on NM_005756.4) | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100492105, COSV100492567; called by muse, mutect2, varscan2
- ADGRL3 | c.3137C>T p.S1046L (on ENST00000506720 / NM_001322402.2; = p.S978L on NM_015236.6) | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV101547203; called by muse, mutect2, varscan2
- AGTR2 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.18); catalogued as COSV64156476; called by muse, mutect2, varscan2
- AHNAK | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV57229985; called by muse, mutect2, varscan2
- AKR1C3 | c.879G>A p.M293I | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as COSV65910407, COSV65910448; called by muse, mutect2, varscan2
- AKT3 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs771134997, COSV55622640, COSV55629501; called by muse, mutect2, varscan2
- ALPK2 | c.5093C>T p.S1698L | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs375605840, COSV64490108; called by muse, mutect2, varscan2
- AMPD1 | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100815188; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6328C>T p.P2110S | Missense Mutation (SNP) | VAF 66/122 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.477); catalogued as COSV51861085; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6329C>T p.P2110L | Missense Mutation (SNP) | VAF 66/122 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV99784230; called by muse, mutect2, varscan2
- ANKRD26 | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs746927502, COSV101063353; called by muse, mutect2, varscan2
- APBB1IP | c.1033G>A p.G345R | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100882235; called by muse, mutect2, varscan2
- APEX2 | c.772T>C p.F258L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV100238559; called by muse, mutect2, varscan2
- APOL6 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs1376928938, COSV101291014; called by muse, mutect2, varscan2
- ARHGAP28 | c.886G>A p.V296I (on ENST00000383472 / NM_001366230.1; = p.V137I on NM_001010000.3) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV99151307; called by muse, mutect2, varscan2
- ARID2 | c.4409C>G p.S1470* | Nonsense Mutation (SNP) | VAF 14/144 reads (10%) | catalogued as COSV100537100, COSV57607789, COSV57617042; called by muse, mutect2
- ARID3B | c.965A>G p.N322S | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100654724; called by muse, mutect2, varscan2
- ARSJ | c.1051G>A p.G351R | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100193052; called by muse, mutect2, varscan2
- ASTN2 | c.2338G>A p.G780S (on ENST00000313400 / NM_001365069.1; = p.G729S on NM_014010.5) | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1249062756, COSV100529894, COSV57805983; called by muse, mutect2, varscan2
- ASXL3 | c.3464C>T p.S1155L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs377619533, COSV99324595, COSV99324757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATCAY | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.163); catalogued as rs373780288, COSV56654866; called by muse, mutect2, varscan2
- ATP13A3 | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as rs1445368674, COSV99757539; called by muse, mutect2, varscan2
- ATP6V0D2 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.484); catalogued as COSV53415531, COSV99572031; called by muse, mutect2, varscan2
- ATP7A | c.148A>T p.I50F | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.821); catalogued as COSV100431497; called by muse, mutect2, varscan2
- ATXN2 | c.1538C>T p.S513L (on ENST00000550104; = p.S353L on NM_002973.4) | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV101112892; called by muse, mutect2, varscan2
- AUTS2 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs758874739, COSV100719360; called by muse, mutect2, varscan2
- AUTS2 | c.2885C>T p.A962V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs866376248, COSV100719362; called by muse, mutect2, varscan2
- AUTS2 | c.3005C>T p.A1002V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.122); catalogued as COSV100719364; called by muse, mutect2, varscan2
- AWAT2 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99339753; called by muse, mutect2, varscan2
- AXL | c.1805G>A p.G602D (on ENST00000301178 / NM_021913.5; = p.G593D on NM_001699.6) | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV99997073; called by muse, mutect2, varscan2
- B3GALNT1 | c.667C>T p.H223Y | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100251984, COSV100252145; called by muse, mutect2, varscan2
- BAAT | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs773128969, COSV52287359; called by muse, mutect2, varscan2
- BCL11A | c.983C>T p.P328L (on ENST00000335712 / NM_001365609.1; = p.P362L on NM_018014.4) | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100186340; called by muse, mutect2, varscan2
- BCL9L | c.4233G>A p.M1411I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV99419994; called by muse, mutect2, varscan2
- BLK | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99377529; called by muse, mutect2, varscan2
- BNC1 | c.2903C>T p.S968L | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs968421847, COSV61756810; called by muse, mutect2, varscan2
- C1QTNF4 | c.44G>A p.W15* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100209374; called by muse, mutect2, varscan2
- C1RL | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.164); catalogued as COSV99864902; called by muse, mutect2, varscan2
- C2orf78 | c.2164C>T p.P722S | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as COSV101281026; called by muse, mutect2, varscan2
- CA4 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.268); catalogued as rs753005580, COSV56280848; called by muse, mutect2, varscan2
- CACNB2 | c.578G>A p.G193E (on ENST00000324631 / NM_201596.3; = p.G138E on NM_000724.4) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as COSV99996022; called by muse, mutect2
- CADPS2 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV100465351; called by muse, mutect2
- CATSPER1 | c.878C>T p.T293I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.334); catalogued as COSV100376198; called by muse, mutect2, varscan2
- CCDC138 | c.1823C>T p.S608F | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54570644; called by muse, mutect2
- CCDC62 | c.1241G>A p.G414E | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV99457584; called by muse, mutect2, varscan2
- CDH17 | c.2308G>A p.G770R | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as COSV99217871; called by muse, mutect2, varscan2
- CDH26 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV54855743; called by muse, mutect2, varscan2
- CDK7 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV99841871; called by muse, mutect2, varscan2
- CDON | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99701864; called by muse, mutect2, varscan2
- CENPE | c.1788A>T p.E596D | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV54385931; called by muse, mutect2, varscan2
- CFAP43 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs371285570; called by muse, mutect2, varscan2
- CFAP53 | c.995G>A p.R332K | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV68352066; called by muse, mutect2, varscan2
- CFAP65 | c.2467C>T p.R823W | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs145857098; called by muse, mutect2, varscan2
- CFAP70 | c.2027G>A p.G676D | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100160968; called by muse, mutect2, varscan2
- CFAP70 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as rs267602573, COSV100160986; called by muse, mutect2, varscan2
- CFTR | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs906983070, COSV50048120; called by muse, mutect2, varscan2
- CHD7 | c.5926C>T p.R1976C | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101418260, COSV71114053; called by muse, varscan2
- CHN1 | c.1178C>T p.T393I | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99789387; called by muse, mutect2, varscan2
- CHRDL1 | c.632G>A p.R211Q (on ENST00000372045; = p.R217Q on NM_145234.4) | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); catalogued as rs920527397, COSV54324326; called by muse, mutect2, varscan2
- CIITA | c.2863C>T p.R955W | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1200008888, COSV60857594; called by muse, mutect2, varscan2
- CLDN20 | c.306G>A p.M102I | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs748397730, COSV100905063; called by muse, mutect2, varscan2
- CLEC6A | c.433G>T p.G145C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101165701; called by muse, mutect2, varscan2
- CNKSR1 | c.1040C>T p.P347L (on ENST00000374253 / NM_001297647.2; = p.P340L on NM_006314.3) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100836771; called by muse, mutect2, varscan2
- CNTN1 | c.1989G>A p.M663I | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.149); catalogued as COSV100751835; called by muse, mutect2, varscan2
- CNTN4 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as COSV101281549; called by muse, mutect2, varscan2
- CNTN5 | c.2599G>A p.V867I | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as COSV54315241, COSV54370423; called by muse, mutect2, varscan2
- COL14A1 | c.4493G>A p.G1498E | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99920370; called by muse, mutect2, varscan2
- COL17A1 | c.2752G>A p.G918R | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100793263; called by muse, mutect2, varscan2
- COL20A1 | c.850G>A p.V284M | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.786); catalogued as COSV100491268; called by muse, mutect2, varscan2
- COL22A1 | c.2915C>T p.P972L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57368404; called by muse, mutect2, varscan2
- COL3A1 | c.1871G>A p.G624E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100483620; called by muse, mutect2, varscan2
- COL6A3 | c.6623C>T p.A2208V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99800727; called by muse, mutect2, varscan2
- CPSF2 | c.1659T>G p.I553M | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100103074; called by muse, mutect2, varscan2
- CPXM1 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758834400, COSV101013818; called by muse, mutect2, varscan2
- CPXM2 | c.1924C>T p.R642C | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780477883, COSV53859463; called by muse, mutect2, varscan2
- CRB1 | c.3826G>A p.E1276K | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.294); catalogued as COSV100958056; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1333A>G p.I445V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs377210956; called by muse, mutect2, varscan2
- CSMD1 | c.9283G>A p.A3095T (on ENST00000520002; = p.A3094T on NM_033225.6) | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100152783, COSV59303561; called by muse, mutect2
- CSMD2 | c.8423G>A p.G2808E | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53977100; called by muse, mutect2, varscan2
- CSMD3 | c.9067G>A p.G3023R (on ENST00000297405 / NM_001363185.1; = p.G2854R on NM_052900.3) | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs894907821, COSV52151243; called by muse, mutect2, varscan2
- CSMD3 | c.4601C>T p.P1534L (on ENST00000297405 / NM_001363185.1; = p.P1430L on NM_052900.3) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV99829617, COSV99844852; called by muse, mutect2, varscan2
- CUL2 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV101039206; called by muse, mutect2, varscan2
- CUL7 | c.4601C>T p.P1534L | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as COSV99539139; called by muse, mutect2, varscan2
- CYP4Z1 | c.1486G>A p.G496R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100497891; called by muse, mutect2, varscan2
- DACH2 | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1013420236, COSV100913760; called by muse, mutect2, varscan2
- DCC | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.905); catalogued as rs145690431, COSV59083434; called by muse, mutect2, varscan2
- DGKZ | c.746C>T p.S249L (on ENST00000454345 / NM_001105540.2; = p.S60L on NM_003646.4) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as rs568978655, COSV58997472; called by muse, mutect2, varscan2
- DMBT1 | c.5285G>A p.G1762E (on ENST00000338354 / NM_001377530.1; = p.G1005E on NM_004406.3) | Missense Mutation (SNP) | VAF 97/316 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.885); catalogued as COSV100353939; called by muse, mutect2, varscan2
- DNAH12 | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV100244391, COSV100244738; called by muse, mutect2, varscan2
- DNAH5 | c.11545G>A p.G3849S | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.231); catalogued as COSV54249947, COSV99453171; called by muse, mutect2, varscan2
- DNAH7 | c.11677G>A p.A3893T | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369244613, COSV56788805; called by muse, mutect2, varscan2
- DNAH7 | c.4840G>A p.G1614R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56770023; called by muse, mutect2, varscan2
- DNAH8 | c.10262C>A p.P3421H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100546865; called by muse, mutect2, varscan2
- DOCK2 | c.2133G>A p.K711= | Splice Region (SNP) | VAF 39/74 reads (53%) | catalogued as COSV99914654; called by muse, mutect2, varscan2
- DOCK8 | c.5158G>A p.G1720S | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.893); catalogued as COSV101210046; called by muse, mutect2, varscan2
- DPP4 | c.1991C>T p.S664L | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100859020; called by muse, mutect2, varscan2
- DPP6 | c.1201C>T p.R401W (on ENST00000377770 / NM_001364500.2; = p.R339W on NM_001936.5) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100127017, COSV100127633; called by muse, mutect2, varscan2
- DSCAM | c.5543C>T p.T1848M | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1292026656, COSV101261330; called by muse, mutect2, varscan2
- DTX1 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV99921997, COSV99922046; called by muse, mutect2, varscan2
- EEFSEC | c.781C>T p.L261F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99631169; called by muse, mutect2
- EIF2B3 | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as COSV100838981; called by muse, mutect2, varscan2
- ELOVL4 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs532735834, COSV63953631; called by muse, mutect2, varscan2
- EMB | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100296688; called by muse, mutect2, varscan2
- ENPEP | c.264G>A p.W88* | Nonsense Mutation (SNP) | VAF 29/78 reads (37%) | catalogued as COSV54453587; called by muse, mutect2, varscan2
- EPHB1 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV67661693; called by muse, mutect2, varscan2
- EPHB3 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.441); catalogued as COSV100383246; called by muse, mutect2, varscan2
- ERBB3 | c.3509C>T p.P1170L | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.043); catalogued as COSV57259171, COSV99917652; called by muse, mutect2, varscan2
- ERGIC1 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV101195026; called by muse, mutect2, varscan2
- ESPL1 | c.3949G>A p.G1317R | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV99229685; called by muse, mutect2, varscan2
- EXOC3L2 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745620424, COSV99374627; called by muse, mutect2, varscan2
- EXTL3 | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0.023); catalogued as rs1207644267, COSV55039045; called by muse, mutect2, varscan2
- EYA4 | c.1757G>A p.G586E (on ENST00000531901 / NM_001301013.1; = p.G580E on NM_004100.5) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866696222, COSV62061225; called by muse, mutect2, varscan2
- EZHIP | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as COSV100539862; called by muse, mutect2, varscan2
- FAM153B | c.580G>A p.E194K (on ENST00000253490; = p.E117K on NM_001265615.1) | Missense Mutation (SNP) | VAF 147/384 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.136); catalogued as rs759403951, COSV99037335, COSV99499097; called by muse, mutect2, varscan2
- FAM214A | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as COSV99957810; called by muse, mutect2, varscan2
- FAM8A1 | c.808A>T p.S270C | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.813); catalogued as COSV99467921; called by muse, mutect2, varscan2
- FASLG | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.788); catalogued as COSV60680352; called by muse, mutect2, varscan2
- FBXO8 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101183720; called by muse, varscan2
- FCN1 | c.486G>A p.M162I | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100878959; called by muse, mutect2, varscan2
- FGD2 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.137); catalogued as rs745324102, COSV51462285, COSV51463688; called by muse, mutect2, varscan2
- FGL2 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV50381470; called by muse, mutect2, varscan2
- FITM1 | c.850C>G p.R284G | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs575266836, COSV52824723, COSV99246457; called by muse, mutect2, varscan2
- FMO3 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as rs866502499, COSV63006994; called by muse, mutect2, varscan2
- FMOD | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.164); catalogued as COSV100724614; called by muse, mutect2, varscan2
- GAL3ST1 | c.458T>A p.V153E | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100143210; called by muse, mutect2, varscan2
- GAL3ST1 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.733); catalogued as COSV100143213; called by muse, mutect2, varscan2
- GALNTL5 | c.1027-1G>A p.X343_splice | Splice Site (SNP) | VAF 19/93 reads (20%) | catalogued as COSV101217924, COSV67179612; called by muse, mutect2, varscan2
- GCOM1 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as COSV99985246; called by muse, mutect2, varscan2
- GDF5 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65499070, COSV65499580; called by muse, mutect2, varscan2
- GFRA2 | c.1218G>A p.Q406= | Splice Region (SNP) | VAF 13/26 reads (50%) | catalogued as COSV100151744; called by muse, mutect2, varscan2
- GJA1 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as CM030458, CM1312154, COSV99247243; called by muse, mutect2, varscan2
- GJA8 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99569629; called by muse, mutect2, varscan2
- GJA8 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV53790742, COSV99569770; called by muse, mutect2, varscan2
- GLCCI1 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as COSV99780668; called by muse, mutect2, varscan2
- GLRB | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1287910151, COSV52414608; called by muse, mutect2, varscan2
- GNB4 | c.236del p.L79* | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as COSV51710128; called by mutect2, pindel, varscan2
- GPR83 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.421); catalogued as COSV54717775; called by muse, mutect2, varscan2
- GRAMD1C | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1323160775, COSV100822965, COSV63982775; called by muse, mutect2, varscan2
- GRIA2 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.551); catalogued as COSV99645670; called by muse, mutect2, varscan2
- GRIA3 | c.1433G>T p.G478V | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99991442; called by muse, mutect2, varscan2
- GRIN2B | c.3505G>A p.G1169R | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.754); catalogued as rs777639067, COSV101663161, COSV74207066; ClinVar: uncertain significance; called by muse, mutect2
- GRIN2B | c.3127T>A p.S1043T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as COSV101663162; called by muse, mutect2
- GRIN2D | c.1714G>A p.V572M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99616863; called by muse, mutect2, varscan2
- GRK2 | c.1864C>T p.L622F | Missense Mutation (SNP) | VAF 82/264 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.856); catalogued as rs1364285412, COSV100398485; called by muse, mutect2, varscan2
- GRM3 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.177); catalogued as rs267601603, COSV64469163; called by muse, mutect2, varscan2
- GRM7 | c.2132C>T p.S711L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as COSV100738103; called by muse, mutect2, varscan2
- GRP | c.275A>T p.E92V | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99901066; called by muse, mutect2, varscan2
- HAPLN1 | c.223C>T p.H75Y | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.625); catalogued as COSV57151182; called by muse, mutect2, varscan2
- HDAC3 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100539744; called by muse, mutect2, varscan2
- HEATR1 | c.2741C>T p.S914F | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100857773; called by muse, mutect2, varscan2
- HECW2 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.86); PolyPhen benign (0.025); catalogued as COSV53654174; called by muse, mutect2, varscan2
- HERC2 | c.9086C>T p.S3029F | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as COSV99876249; called by muse, mutect2, varscan2
- HFM1 | c.2914C>T p.P972S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779478584, COSV54032894, COSV99645303; called by muse, mutect2, varscan2
- HIVEP2 | c.5556G>A p.M1852I | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.914); catalogued as COSV99175087; called by muse, mutect2, varscan2
- HIVEP3 | c.3328C>T p.P1110S | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99913679; called by muse, mutect2, varscan2
- HNRNPM | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as rs770127136, COSV99725821; called by muse, mutect2, varscan2
- HRG | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs199501331, COSV51646296; called by muse, mutect2, varscan2
- HTR3E | c.1294G>A p.D432N (on ENST00000415389 / NM_001256613.1; = p.D447N on NM_182589.2) | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100094438; called by muse, mutect2, varscan2
- HYDIN | c.13763C>T p.S4588F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV66637546; called by muse, mutect2, varscan2
- IBTK | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60392553; called by muse, mutect2, varscan2
- IDO1 | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99503571; called by muse, mutect2, varscan2
- IGHV3-15 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs782356020; called by muse, mutect2, varscan2
- IGKC | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.418); catalogued as rs373698975; called by muse, mutect2, varscan2
- IGSF1 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100812269, COSV63841437; called by muse, mutect2, varscan2
- INTS6L | c.1931T>G p.V644G | Missense Mutation (SNP) | VAF 72/177 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.434); catalogued as COSV100878253; called by muse, mutect2, varscan2
- ITIH6 | c.2158A>G p.T720A | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV99513817; called by muse, mutect2, varscan2
- ITM2A | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV100964480; called by muse, mutect2, varscan2
- ITSN2 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1187444779, COSV100744064; called by muse, mutect2, varscan2
- JAKMIP1 | c.1277G>C p.R426P | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV51545250, COSV99290558; called by muse, mutect2, varscan2
- KALRN | c.3340C>T p.R1114C | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53783608; called by muse, mutect2, varscan2
- KAT6A | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 78/258 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55912960; called by muse, mutect2, varscan2
- KCNH8 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.596); catalogued as COSV100109012; called by muse, mutect2, varscan2
- KCNK13 | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); catalogued as rs770204298, COSV56413418; called by muse, mutect2, varscan2
- KCNT2 | c.2036G>A p.G679E | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267598261, COSV54073484; called by muse, mutect2, varscan2
- KIAA0408 | c.1204C>A p.H402N | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as COSV100847034; called by muse, mutect2, varscan2
- KIF18A | c.2101C>T p.Q701* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as COSV99589035; called by muse, mutect2, varscan2
- KIF23 | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99532637; called by muse, mutect2, varscan2
- KIFC2 | c.2311C>T p.P771S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.205); catalogued as rs1564750716, COSV100023955; called by muse, mutect2
- KLHL4 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.377); catalogued as rs746132442, COSV100910105; called by muse, mutect2, varscan2
- KMT2D | c.6426C>A p.F2142L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.262); catalogued as COSV99985182; called by muse, mutect2, varscan2
- KRT12 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV99289092; called by muse, mutect2, varscan2
- KRTAP10-2 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as rs587724578, COSV100555178; called by muse, mutect2, varscan2
- LALBA | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV56395811; called by muse, mutect2, varscan2
- LAMA3 | c.4291G>A p.E1431K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV100557540; called by muse, mutect2, varscan2
- LARP6 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100151025; called by muse, mutect2, varscan2
- LAT | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100209250; called by muse, mutect2, varscan2
- LRFN2 | c.2168C>T p.S723F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100599849; called by muse, mutect2, varscan2
- LRG1 | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV100014899; called by muse, mutect2, varscan2
- LRRK1 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV52615253; called by muse, mutect2, varscan2
- LRRN3 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs772927353, COSV100072754; called by muse, mutect2, varscan2
- MACF1 | c.823G>C p.D275H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100486050; called by muse, mutect2, varscan2
- MAN1B1 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs754933555, COSV64306148; called by muse, mutect2, varscan2
- MERTK | c.1661C>T p.S554F | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867179424, COSV99775162; called by muse, mutect2, varscan2
- MMP28 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs756987596; called by muse, mutect2, varscan2
- MOGAT3 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as rs139340331, COSV56175477; called by muse, mutect2, varscan2
- MPO | c.1653G>A p.M551I | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.08); catalogued as COSV99229242; called by muse, mutect2, varscan2
- MRPL58 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); catalogued as COSV100043039; called by muse, mutect2, varscan2
- MTNR1A | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.208); catalogued as rs186753852; called by muse, mutect2, varscan2
- MUC16 | c.32506C>T p.P10836S | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.044); catalogued as COSV67494553; called by muse, mutect2, varscan2
- MUC16 | c.28055G>A p.R9352K | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.161); catalogued as COSV67472359; called by muse, mutect2, varscan2
- MUC3A | c.7691G>A p.S2564N | Missense Mutation (SNP) | VAF 192/698 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs377752629; called by muse, mutect2, varscan2
- MXD3 | c.281C>T p.T94I | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100293757; called by muse, mutect2, varscan2
- MXRA5 | c.5839G>A p.V1947M | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV54248924; called by muse, mutect2, varscan2
- MYEF2 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs371575787; called by muse, mutect2, varscan2
- MYL9 | c.362A>C p.D121A | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV99641148; called by muse, mutect2, varscan2
- MYLK3 | c.1789C>T p.L597F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101189091; called by muse, mutect2, varscan2
- MYO7B | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768991281, COSV67348154; called by muse, mutect2, varscan2
- MYO9A | c.6146C>T p.S2049F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61855277; called by muse, mutect2, varscan2
- MYOCD | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100591273; called by muse, mutect2, varscan2
- N6AMT1 | c.616C>A p.L206I | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100375074; called by muse, mutect2, varscan2
- NAA11 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.427); catalogued as COSV99727556; called by muse, mutect2, varscan2
- NALCN | c.3582G>A p.P1194= | Splice Region (SNP) | VAF 5/35 reads (14%) | catalogued as rs201831882, COSV51951314; called by muse, mutect2, varscan2
- NCF2 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 117/341 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); catalogued as COSV100838936, COSV62314786; called by muse, mutect2, varscan2
- NETO1 | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868861139, COSV55007105; called by muse, mutect2, varscan2
- NHEJ1 | c.878A>T p.K293M | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100592164; called by muse, mutect2, varscan2
- NOVA1 | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57473034, COSV99948497; called by muse, mutect2, varscan2
- NUDT5 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV100968827; called by muse, mutect2, varscan2
- NUMA1 | c.5228G>A p.R1743H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs759463716, COSV99474946; called by muse, mutect2, varscan2
- ODF4 | c.591G>A p.A197= | Splice Region (SNP) | VAF 25/64 reads (39%) | catalogued as rs777173403, COSV100071798; called by muse, mutect2, varscan2
- OPHN1 | c.1645C>T p.Q549* | Nonsense Mutation (SNP) | VAF 31/110 reads (28%) | catalogued as CM054055, COSV100830723; called by muse, mutect2, varscan2
- OR11H1 | c.857C>A p.T286N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99421953; called by mutect2, varscan2
- OR1N1 | c.626T>G p.F209C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100509815; called by muse, mutect2, varscan2
- OR4N5 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100374201, COSV61320719; called by muse, mutect2, varscan2
- OR52M1 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as rs145962402; called by muse, mutect2, varscan2
- OR8B12 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.127); catalogued as rs1340060473, COSV60911390; called by muse, mutect2, varscan2
- OTOGL | c.4723G>A p.E1575K (on ENST00000547103; = p.E1566K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.691); catalogued as rs577690596, COSV54014641; called by muse, mutect2, varscan2
- P3H3 | c.856C>A p.H286N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV99301586; called by muse, mutect2, varscan2
- PANX2 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0.136); catalogued as rs1293666177, COSV50292734; called by muse, mutect2
- PAPPA2 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.89); PolyPhen benign (0.045); catalogued as rs763247787, COSV62781271; called by muse, mutect2, varscan2
- PAPPA2 | c.1912G>A p.D638N | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as rs1168232006, COSV62772967; called by muse, mutect2, varscan2
- PARD3B | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100594886; called by muse, mutect2, varscan2
- PARP4 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs199585627, COSV67962766; called by muse, mutect2, varscan2
- PCDHAC1 | c.2386A>T p.I796F | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.067); catalogued as COSV99169312; called by muse, mutect2, varscan2
- PENK | c.776A>G p.K259R | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100152449; called by muse, mutect2, varscan2
- PENK | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV59241193; called by muse, mutect2, varscan2
- PEX11B | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV100995013, COSV100995032; called by muse, mutect2, varscan2
- PHF8 | c.1565C>T p.S522F (on ENST00000357988 / NM_001184896.1; = p.S486F on NM_015107.3) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV100153686; called by muse, mutect2, varscan2
- PHKA1 | c.3208G>A p.G1070R | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59802053; called by muse, mutect2, varscan2
- PIGA | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV100363510; called by muse, mutect2, varscan2
- PIGG | c.1201C>A p.L401I | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV99574257; called by muse, mutect2, varscan2
- PIK3CD | c.1240G>T p.A414S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.842); catalogued as COSV100740450; called by muse, mutect2, varscan2
- PIM1 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.249); catalogued as COSV65165136, COSV65166309; called by muse, mutect2, varscan2
- PKM | c.698T>C p.V233A | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV100065160; called by muse, mutect2, varscan2
- PLCH1 | c.1348C>A p.L450I (on ENST00000340059 / NM_001130960.2; = p.L462I on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.338); catalogued as COSV100398024; called by muse, mutect2, varscan2
- PLEKHB2 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV99301811; called by muse, mutect2, varscan2
- POLR1B | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV99638362; called by muse, mutect2, varscan2
- POM121L12 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1689291, COSV68692218; called by muse, mutect2, varscan2
- POU5F2 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); catalogued as COSV101232916; called by muse, mutect2, varscan2
- PPIL1 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV65472335; called by muse, mutect2, varscan2
- PPIP5K2 | c.3389C>T p.P1130L (on ENST00000358359 / NM_001276277.3; = p.P1109L on NM_015216.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV100384151; called by muse, mutect2, varscan2
- PPP1R3A | c.58A>C p.N20H | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV99494009; called by muse, mutect2, varscan2
- PPRC1 | c.4150C>T p.R1384W | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs766885739, COSV99531991; called by muse, mutect2, varscan2
- PRDM15 | c.3048G>T p.E1016D | Missense Mutation (SNP) | VAF 73/261 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); catalogued as COSV99520821; called by muse, mutect2, varscan2
- PRKAG3 | c.516G>A p.W172* | Nonsense Mutation (SNP) | VAF 33/100 reads (33%) | catalogued as COSV99292096; called by muse, mutect2, varscan2
- PRKCA | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.426); catalogued as rs1191887100, COSV99435874; called by muse, mutect2, varscan2
- PROKR1 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100375691; called by muse, mutect2, varscan2
- PRPF39 | c.1783C>T p.Q595* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV53533440, COSV99361124; called by muse, mutect2, varscan2
- PRR30 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs149656537; called by muse, mutect2, varscan2
- PYGO1 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100114799; called by muse, mutect2, varscan2
- QSOX2 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.631); catalogued as COSV100699853; called by muse, mutect2, varscan2
- RAB35 | c.476A>T p.E159V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV99984683; called by muse, mutect2, varscan2
- RASAL2 | c.1471C>T p.L491F | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100862844; called by muse, mutect2, varscan2
- RBFOX1 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100303217; called by muse, mutect2, varscan2
- RBM5 | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.308); catalogued as rs867690952, COSV100762455; called by muse, mutect2, varscan2
- RBMX | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 79/231 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.118); catalogued as COSV100284914; called by muse, mutect2, varscan2
- RBP3 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.656); catalogued as rs150902800; called by muse, mutect2, varscan2
- REPS2 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100381559; called by muse, mutect2, varscan2
- RGS6 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100666886; called by muse, mutect2, varscan2
- RIPK4 | c.2384A>C p.H795P (on ENST00000352483; = p.H747P on NM_020639.3) | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100205300; called by muse, mutect2, varscan2
- RIPPLY3 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as COSV100289415; called by muse, mutect2, varscan2
- ROPN1 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs776728938, COSV99481551; called by muse, mutect2, varscan2
- RTL5 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.081); catalogued as COSV101030292, COSV65454187; called by muse, mutect2, varscan2
- SAA1 | c.54C>A p.S18R | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV100736556; called by muse, mutect2, varscan2
- SAA1 | c.55C>T p.R19* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as rs373249018; called by muse, mutect2, varscan2
- SAGE1 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV100187670, COSV61017831; called by muse, mutect2, varscan2
- SAMD3 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.825); catalogued as COSV100148394; called by muse, mutect2, varscan2
- SCN11A | c.4444G>A p.G1482R | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as COSV100182249; called by muse, mutect2, varscan2
- SCN2A | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV51836073, COSV51840235; called by muse, mutect2, varscan2
- SCNN1B | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.692); catalogued as rs80311498, COSV100225905; called by muse, mutect2, varscan2
- SEL1L2 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99533789; called by muse, mutect2, varscan2
- SETD2 | c.1820C>T p.P607L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV100339824; called by muse, mutect2, varscan2
- SETD5 | c.1820C>T p.P607L | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760992603, COSV100201026; called by muse, mutect2, varscan2
- SF3B2 | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV59428608; called by muse, mutect2
- SH2D1A | c.99C>G p.D33E | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV100758353; called by muse, mutect2, varscan2
- SH3KBP1 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV101115100; called by muse, mutect2, varscan2
- SIGLEC1 | c.2785C>T p.R929C | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as rs138170063, COSV52467948; called by muse, mutect2, varscan2
- SIGLEC10 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as rs1468892389, COSV100219368; called by muse, mutect2
- SIGLEC10 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as COSV100219371; called by muse, mutect2
- SLAMF9 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs866515610, COSV100928180; called by muse, mutect2, varscan2
- SLC12A5 | c.2224C>T p.H742Y (on ENST00000454036 / NM_001134771.2; = p.H719Y on NM_020708.5) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV54801177; called by muse, mutect2, varscan2
- SLC15A2 | c.1057C>T p.L353F | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55199900, COSV55201116; called by muse, mutect2, varscan2
- SLC15A3 | c.1705G>A p.G569S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV99136881; called by muse, mutect2, varscan2
- SLC25A21 | c.775C>T p.Q259* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as COSV58728995; called by muse, mutect2, varscan2
- SLC51A | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99580418; called by muse, mutect2, varscan2
- SLC52A1 | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as rs749137629, COSV99643508; called by muse, mutect2, varscan2
- SLC6A1 | c.533G>A p.S178N | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.737); catalogued as rs1291289201, COSV99823128; called by muse, mutect2, varscan2
- SLC6A20 | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as rs536701181, COSV100653939; called by muse, mutect2, varscan2
- SLC7A11 | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1338903019, COSV54934304; called by muse, mutect2, varscan2
- SLC9A2 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV52131978; called by muse, mutect2, varscan2
- SLCO1B1 | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99918972; called by muse, mutect2, varscan2
- SMCHD1 | c.3104A>G p.H1035R | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99862378; called by muse, mutect2, varscan2
- SNED1 | c.3101C>T p.T1034I | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as COSV100123284; called by muse, mutect2, varscan2
- SORCS3 | c.958T>A p.Y320N | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100865574; called by muse, mutect2, varscan2
- SOWAHD | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0.011); catalogued as COSV100673160; called by muse, mutect2, varscan2
- SPATA31D1 | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs1249841314, COSV100783015; called by muse, mutect2, varscan2
- SPEM2 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | catalogued as COSV60366991; called by muse, mutect2, varscan2
- SS18 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV99294385; called by muse, mutect2, varscan2
- STK31 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV100669851; called by muse, mutect2, varscan2
- STPG1 | c.268G>A p.G90R (on ENST00000337248 / NM_001199013.2; = p.G43R on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99134358; called by muse, mutect2, varscan2
- SULT2A1 | c.473-1G>C p.X158_splice | Splice Site (SNP) | VAF 29/84 reads (35%) | catalogued as COSV99705542; called by muse, mutect2, varscan2
- SYN3 | c.976G>A p.V326M | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100249849; called by muse, mutect2, varscan2
- SYNJ2 | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756823954, COSV62898861; called by muse, mutect2, varscan2
- SYT15 | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100970633; called by mutect2, varscan2
- SYTL3 | c.763G>A p.D255N (on ENST00000611299 / NM_001242394.1; = p.D187N on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs553737971, COSV99792430; called by muse, mutect2, varscan2
- TACC2 | c.2477C>T p.S826F | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV57750987; called by muse, mutect2, varscan2
- TACC2 | c.3425G>A p.G1142E | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1198546831, COSV100553521; called by muse, mutect2, varscan2
- TAF6L | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV99585407; called by muse, mutect2, varscan2
- TAS1R2 | c.1937C>T p.S646F | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1489917240, COSV100946330; called by muse, mutect2, varscan2
- TBCEL | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99412377; called by muse, varscan2
- TDRD1 | c.1881G>A p.M627I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99315007; called by muse, mutect2, varscan2
- TECTA | c.5233G>A p.G1745R | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs201488025; called by muse, mutect2, varscan2
- TEF | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as rs777214421, COSV99842020; called by muse, mutect2, varscan2
- TEKT5 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99296346; called by muse, mutect2, varscan2
- TENM1 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs1569402825, COSV100950657; called by muse, mutect2, varscan2
- TENM2 | c.5963A>G p.N1988S (on ENST00000518659 / NM_001122679.2; = p.N1749S on NM_001080428.3) | Missense Mutation (SNP) | VAF 121/197 reads (61%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as COSV69143859; called by muse, mutect2, varscan2
- TGFBR3 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as COSV53024545; called by muse, mutect2, varscan2
- THBS2 | c.447G>A p.W149* | Nonsense Mutation (SNP) | VAF 24/84 reads (29%) | catalogued as COSV100828029, COSV64677530; called by muse, mutect2, varscan2
- THEMIS | c.974G>A p.S325N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.946); catalogued as COSV100965519; called by muse, mutect2, varscan2
- THRB | c.811C>T p.H271Y | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.18); catalogued as COSV99769394; called by muse, mutect2, varscan2
- TLR8 | c.2773G>A p.G925R (on ENST00000218032 / NM_138636.5; = p.G943R on NM_016610.4) | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54317339; called by muse, mutect2, varscan2
- TMC1 | c.1458G>A p.M486I | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV52777553; called by muse, mutect2, varscan2
- TMEM273 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100939720; called by muse, mutect2, varscan2
- TNFRSF10A | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.284); catalogued as rs754090248, COSV99646158, COSV99646318; called by muse, mutect2, varscan2
- TNFRSF19 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.013); catalogued as COSV99947643; called by muse, mutect2, varscan2
- TOR2A | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 40/105 reads (38%) | catalogued as COSV100263210; called by muse, mutect2, varscan2
- TP63 | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV53199759; called by muse, mutect2, varscan2
- TPD52L1 | c.489G>A p.T163= | Splice Region (SNP) | VAF 30/73 reads (41%) | catalogued as rs267600791, COSV59191475; called by muse, mutect2, varscan2
- TRAV12-3 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs370888273; called by muse, mutect2, varscan2
- TRAV25 | c.313T>C p.Y105H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769845215; called by muse, varscan2
- TRERF1 | c.1638G>A p.E546= | Splice Region (SNP) | VAF 13/52 reads (25%) | catalogued as COSV61671256; called by muse, mutect2, varscan2
- TTC27 | c.1567C>T p.R523W | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as rs746270211, COSV100513474; called by muse, mutect2, varscan2
- TTN | c.88948G>A p.E29650K (on ENST00000591111; = p.E22226K on NM_003319.4) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | PolyPhen probably damaging (0.994); catalogued as COSV59907883; called by muse, mutect2, varscan2
- TTN | c.83462C>T p.A27821V (on ENST00000591111; = p.A20397V on NM_003319.4) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | PolyPhen benign (0.003); catalogued as COSV100626230; called by muse, mutect2, varscan2
- TTN | c.46223G>A p.G15408E (on ENST00000591111; = p.G7984E on NM_003319.4) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | PolyPhen probably damaging (1); catalogued as COSV100626232; called by muse, mutect2, varscan2
- TWSG1 | c.466C>T p.H156Y | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.154); catalogued as rs1406780612, COSV100039502; called by muse, mutect2, varscan2
- UBR4 | c.10591C>T p.P3531S | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100921593; called by muse, mutect2, varscan2
- UGT2B10 | c.854A>G p.K285R | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs376282977; called by muse, mutect2, varscan2
- UNC5B | c.2467C>T p.Q823* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as COSV100101234, COSV58981547; called by muse, mutect2, varscan2
- USP24 | c.2851C>T p.H951Y | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99600766; called by muse, mutect2, varscan2
- VBP1 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.454); catalogued as COSV99660961; called by muse, mutect2, varscan2
- VDR | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99968953, COSV99968968; called by muse, mutect2, varscan2
- VIPAS39 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs376797384; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13A | c.7313C>T p.S2438F | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.387); catalogued as COSV62440475; called by muse, mutect2, varscan2
- VPS18 | c.1202C>T p.T401I | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV99592377; called by muse, mutect2, varscan2
- VWA2 | c.763G>A p.G255S | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as rs746456782, COSV100073921; called by muse, mutect2, varscan2
- VWF | c.6094C>T p.P2032S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV99779939; called by muse, mutect2, varscan2
- WDR33 | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as COSV100460570; called by muse, mutect2, varscan2
- WDR47 | c.1735C>T p.P579S (on ENST00000369962 / NM_001142551.2; = p.P580S on NM_014969.5) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100728428; called by muse, mutect2, varscan2
- WDR7 | c.3691G>A p.D1231N | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs761722912, COSV54360164, COSV99590207; called by muse, mutect2, varscan2
- XKR4 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59312916; called by muse, mutect2, varscan2
- XPOT | c.947A>G p.K316R | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.034); catalogued as COSV100225713; called by muse, mutect2, varscan2
- XYLB | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV99264352, COSV99264457; called by muse, mutect2, varscan2
- YIPF1 | c.220T>A p.S74T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV99301125; called by muse, mutect2, varscan2
- ZBTB4 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs1454107808, COSV60978171; called by muse, mutect2, varscan2
- ZBTB4 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as COSV100263681; called by muse, mutect2, varscan2
- ZNF292 | c.3583C>T p.H1195Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.229); catalogued as COSV100371007; called by muse, mutect2, varscan2
- ZNF445 | c.2899G>T p.G967* | Nonsense Mutation (SNP) | VAF 43/97 reads (44%) | catalogued as COSV101253869; called by muse, mutect2, varscan2
- ZNF462 | c.3607C>T p.R1203W | Missense Mutation (SNP) | VAF 159/463 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs748634199, COSV52935098; called by muse, mutect2, varscan2
- ZNF473 | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); catalogued as COSV99569052; called by muse, mutect2, varscan2
- ZNF536 | c.3304C>T p.P1102S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV100835714; called by muse, mutect2, varscan2
- ZNF597 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100072121; called by muse, mutect2, varscan2
- ZNF75D | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV100883687; called by muse, mutect2, varscan2
- ZNF780B | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.595); catalogued as rs756915204, COSV55467134; called by muse, mutect2, varscan2
- ZNF786 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs894012539, COSV99070112; called by muse, mutect2, varscan2
- ZNF80 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs143027025; called by muse, mutect2, varscan2
- ZNF808 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.892); catalogued as rs776544335, COSV100708157; called by muse, mutect2, varscan2
- ZNHIT6 | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV100995702; called by muse, mutect2, varscan2
- ZNRF4 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs775439600, COSV55774805; called by muse, mutect2, varscan2
- ANKRA2 | c.486_490del p.M162Ifs*17 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
- DNAH7 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.887); called by muse, mutect2
- HERC2 | c.2976del p.I993Lfs*32 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- IBTK | c.2779del p.Y927Tfs*4 | Frame Shift Del (DEL) | VAF 5/16 reads (31%) | called by mutect2, varscan2
- KIR3DL2 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 79/273 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- KRR1 | c.592G>A p.G198S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); called by muse, mutect2
- KRR1 | c.590G>A p.S197N | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- OR8G2P | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PAXIP1 | c.703dup p.S235Ffs*3 | Frame Shift Ins (INS) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- WASF2 | c.177_184del p.T60Lfs*8 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- ABCA8 | c.3012C>T p.I1004= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1301984289, COSV52209799; called by muse, mutect2
- ABCC3 | c.1155C>T p.I385= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV53319145; called by muse, mutect2, varscan2
- ABCG5 | c.1185C>T p.I395= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV99575581; called by muse, mutect2, varscan2
- ACSM2A | c.1248C>T p.P416= (on ENST00000219054; = p.P337= on NM_001308169.2) | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs773386769, COSV99525635; called by muse, mutect2, varscan2
- ACSM2A | c.1446G>A p.L482= (on ENST00000219054; = p.L403= on NM_001308169.2) | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs763922769, COSV99525636; called by muse, mutect2, varscan2
- ADAMTS7 | c.3468C>T p.F1156= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs1451533278, COSV66305859; called by muse, mutect2, varscan2
- ADNP | c.684C>T p.F228= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs1568710655, COSV100823842; called by muse, mutect2, varscan2
- ADORA2A | c.63C>T p.I21= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100418122; called by muse, mutect2, varscan2
- AKT1 | c.627C>T p.F209= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100838274; called by muse, mutect2, varscan2
- ALDH2 | c.849C>T p.T283= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV99923205, COSV99923258; called by muse, mutect2, varscan2
- ANOS1 | c.1081C>T p.L361= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV99391314; called by muse, mutect2, varscan2
- ANOS1 | c.1080C>T p.I360= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs777960017, COSV52924191, COSV99391315; called by muse, mutect2, varscan2
- ARID2 | c.3306C>T p.A1102= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV100536851; called by muse, mutect2, varscan2
- ARMCX1 | c.1155T>A p.I385= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV100863234; called by muse, mutect2, varscan2
- ARNTL | c.1467G>A p.R489= (on ENST00000403290 / NM_001297719.2; = p.R488= on NM_001178.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100724850; called by muse, mutect2, varscan2
- ATP13A5 | c.1698C>T p.D566= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV100665601; called by muse, mutect2, varscan2
- B3GAT1 | c.579C>T p.F193= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs765229137, COSV56995948; called by muse, mutect2, varscan2
- B4GALT2 | c.369G>A p.R123= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as COSV99356613; called by muse, mutect2, varscan2
- BHMT2 | c.405G>A p.Q135= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV99670273; called by muse, mutect2, varscan2
- CAPN15 | c.2733C>T p.P911= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs1247735297, COSV54838692; called by muse, mutect2
- CARD6 | c.159C>A p.L53= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV54564411, COSV99621184; called by muse, mutect2, varscan2
- CARD6 | c.160C>T p.L54= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV99621187; called by muse, mutect2, varscan2
- CATSPERD | c.348C>T p.V116= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV101062760; called by muse, mutect2, varscan2
- CC2D1A | c.1285C>T p.L429= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV100528669; called by muse, mutect2
- CCDC158 | c.1935C>T p.L645= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV101187348; called by muse, mutect2, varscan2
- CD19 | c.531G>A p.R177= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs754656596, COSV100218244; called by muse, mutect2, varscan2
- CDH26 | c.1335C>T p.S445= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs773935366, COSV54843160; called by muse, mutect2, varscan2
- CEP164 | c.1899C>T p.I633= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV99634164; called by muse, mutect2, varscan2
- CFAP43 | c.126C>T p.Y42= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV99530958; called by muse, mutect2, varscan2
- CFAP45 | c.1323G>A p.R441= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100928653; called by muse, mutect2, varscan2
- CFH | c.3573G>A p.S1191= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as rs774650020, COSV66411127; called by muse, mutect2, varscan2
- CFHR5 | c.1683G>A p.G561= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV56829469; called by muse, mutect2, varscan2
- CKMT2 | c.558G>A p.R186= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as COSV99562467; called by muse, mutect2, varscan2
- CNOT1 | c.6042G>A p.Q2014= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99801021; called by muse, mutect2, varscan2
- CNTROB | c.51C>T p.L17= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as COSV100366561; called by muse, mutect2, varscan2
- CNTROB | c.52C>T p.L18= | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as COSV100366562; called by muse, mutect2, varscan2
- COL4A4 | c.2928A>G p.E976= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV100307543; called by muse, mutect2, varscan2
- COL6A3 | c.4227G>A p.T1409= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as rs142938239, COSV99798963; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPXM1 | c.1111C>T p.L371= | Silent (SNP) | VAF 31/121 reads (26%) | catalogued as COSV66045258; called by muse, mutect2, varscan2
- DDX10 | c.717T>G p.V239= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as COSV100489874; called by muse, mutect2, varscan2
- DEFB127 | c.174G>A p.K58= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV101213881; called by muse, mutect2, varscan2
- DKK2 | c.321G>A p.K107= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV99569402; called by muse, mutect2, varscan2
- DLG5 | c.1788C>T p.F596= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100967800; called by muse, mutect2, varscan2
- DNAH2 | c.2481G>A p.R827= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV101209549; called by muse, mutect2, varscan2
- DNAJC1 | c.1513C>T p.L505= | Silent (SNP) | VAF 44/137 reads (32%) | catalogued as rs1444684773, COSV100981416; called by muse, mutect2, varscan2
- DOCK4 | c.5625C>T p.P1875= | Silent (SNP) | VAF 61/97 reads (63%) | catalogued as COSV101447953; called by muse, mutect2, varscan2
- DPP6 | c.1200C>T p.N400= (on ENST00000377770 / NM_001364500.2; = p.N338= on NM_001936.5) | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as COSV100127012, COSV100127630; called by muse, mutect2, varscan2
- DSE | c.447C>T p.V149= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as rs768494599, COSV100528750; called by muse, mutect2, varscan2
- EIF3B | c.2088G>A p.K696= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as COSV100703818; called by muse, mutect2, varscan2
- ELL2 | c.189C>T p.L63= | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as COSV99427179, COSV99427827; called by muse, mutect2, varscan2
- EME1 | c.564A>G p.T188= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV99869097; called by muse, mutect2, varscan2
- EPHA3 | c.2574G>A p.L858= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV100347982; called by muse, mutect2, varscan2
- ERC2 | c.726C>T p.L242= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as rs764188610, COSV99888655; called by muse, mutect2, varscan2
- EWSR1 | c.1731C>T p.G577= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs1183296447, COSV100132001; called by muse, mutect2, varscan2
- FAM171B | c.1536G>A p.K512= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100488918; called by muse, mutect2, varscan2
- FAM83F | c.1290G>A p.G430= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs1304428669, COSV100328938; called by muse, mutect2, varscan2
- FBXO34 | c.30G>A p.Q10= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100572137; called by muse, mutect2
- FYB2 | c.549G>A p.R183= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as COSV58585359; called by muse, mutect2, varscan2
- GALNT2 | c.288G>A p.Q96= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as COSV100795868; called by muse, mutect2, varscan2
- GATAD2A | c.1126C>T p.L376= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV99390625; called by muse, mutect2, varscan2
- GATM | c.1200C>T p.S400= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV67540602; called by muse, mutect2
- GLI2 | c.1653C>T p.I551= (on ENST00000361492 / NM_001374353.1; = p.I568= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 100/291 reads (34%) | catalogued as COSV100084109; called by muse, mutect2, varscan2
- GPR21 | c.933C>T p.F311= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV101016504; called by muse, mutect2, varscan2
- GPRC6A | c.1206C>T p.F402= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100114682; called by muse, mutect2, varscan2
- GRID1 | c.2769C>T p.T923= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100026019; called by muse, mutect2, varscan2
- GRIN2B | c.3129C>T p.S1043= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1247142777, COSV74205640; called by muse, mutect2
- GRK2 | c.1863C>T p.L621= | Silent (SNP) | VAF 82/263 reads (31%) | catalogued as rs1400762877, COSV100398584; called by muse, mutect2, varscan2
- H3-5 | c.42G>A p.G14= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs1425416749, COSV100461779; called by muse, mutect2, varscan2
- HABP2 | c.1051C>T p.L351= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100668075; called by muse, mutect2, varscan2
- HCRTR2 | c.900G>A p.R300= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV63798517; called by muse, mutect2, varscan2
- HGD | c.1086G>A p.G362= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV99381331; called by muse, mutect2, varscan2
- HOXC9 | c.765C>T p.T255= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as rs908837504, COSV100327468; called by muse, mutect2, varscan2
- IER3 | c.400C>T p.L134= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99458326; called by muse, mutect2, varscan2
- IGHV3-53 | c.267C>T p.S89= | Silent (SNP) | VAF 90/371 reads (24%) | called by muse, mutect2, varscan2
- IGLC3 | c.45C>T p.S15= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs1205468508; called by muse, mutect2, varscan2
- IGSF1 | c.1692C>T p.F564= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV100812268; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1890C>T p.Y630= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs764610412, COSV56271758; called by muse, mutect2, varscan2
- INSIG1 | c.723C>T p.F241= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as COSV100453077; called by muse, mutect2, varscan2
- ITGAV | c.2241C>T p.I747= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV53718787; called by muse, mutect2, varscan2
- KEL | c.762G>A p.L254= | Silent (SNP) | VAF 46/98 reads (47%) | catalogued as COSV62338972; called by muse, mutect2, varscan2
- KHNYN | c.774G>A p.E258= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV99250063; called by muse, mutect2, varscan2
- KLK6 | c.484C>T p.L162= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as COSV100037822; called by muse, mutect2, varscan2
- LMOD1 | c.501G>A p.V167= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100939251; called by muse, mutect2
- LMOD3 | c.747G>A p.R249= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as COSV101342024; called by muse, mutect2, varscan2
- LRIT2 | c.1560C>T p.S520= | Silent (SNP) | VAF 56/142 reads (39%) | catalogued as COSV60564803; called by muse, mutect2, varscan2
- LRRC47 | c.762C>T p.I254= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV100989351; called by muse, mutect2, varscan2
- MAMDC2 | c.684C>T p.F228= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV101015749; called by muse, mutect2, varscan2
- MGAM | c.5460C>T p.V1820= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV101527713; called by muse, mutect2, varscan2
- MICAL1 | c.666C>T p.F222= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs201881865, COSV62196310; called by muse, mutect2, varscan2
- MMP19 | c.378G>A p.R126= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as COSV100491240, COSV59453044; called by muse, mutect2, varscan2
- MPZL2 | c.297G>A p.G99= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs1375711936, COSV54048841; called by muse, mutect2, varscan2
- MTNR1A | c.816C>T p.I272= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV56155629; called by muse, mutect2, varscan2
- MUC16 | c.718C>T p.L240= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV101201164; called by muse, mutect2, varscan2
- MUC16 | c.717C>T p.D239= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV101201165; called by muse, mutect2, varscan2
- MYH4 | c.2094G>A p.R698= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV55123347; called by muse, mutect2, varscan2
- MYLIP | c.1152C>T p.A384= | Silent (SNP) | VAF 36/167 reads (22%) | catalogued as COSV100786019; called by muse, mutect2, varscan2
- MYMK | c.600G>A p.K200= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV101301171; called by muse, mutect2, varscan2
- MYO15A | c.459G>A p.Q153= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs1161718422, COSV99230604; called by muse, mutect2, varscan2
- MYO5C | c.2337G>A p.E779= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV99955303; called by muse, mutect2, varscan2
- NCOR1 | c.480T>A p.I160= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs149251801, COSV99252597; called by muse, varscan2
- NFAT5 | c.375C>T p.T125= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as COSV100591116; called by muse, mutect2, varscan2
- NHS | c.3351G>A p.L1117= | Silent (SNP) | VAF 50/139 reads (36%) | catalogued as COSV101196917; called by muse, mutect2, varscan2
- NLGN4X | c.1206C>T p.F402= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs771730382, COSV99323541; called by muse, mutect2, varscan2
- NLRP3 | c.1104C>T p.I368= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV100276529; called by muse, mutect2, varscan2
- NLRP3 | c.1500C>T p.F500= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100276530; called by muse, mutect2, varscan2
- NLRP7 | c.1252C>T p.L418= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs1184677288, COSV100053230; called by muse, mutect2, varscan2
- NLRX1 | c.1432C>T p.L478= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs1323804226, COSV99424427, COSV99424776; called by muse, mutect2, varscan2
- NOS3 | c.1317G>A p.G439= | Silent (SNP) | VAF 67/112 reads (60%) | catalogued as COSV52491460; called by muse, mutect2, varscan2
- NPAP1 | c.984G>A p.R328= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as COSV100276366, COSV61505370; called by muse, mutect2, varscan2
- NRP2 | c.2154C>T p.F718= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV99785407; called by muse, mutect2, varscan2
- NRP2 | c.2553G>A p.S851= (on ENST00000360409 / NM_201266.2; = p.S846= on NM_003872.3) | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as rs199691517, COSV63375768; called by muse, mutect2, varscan2
- NUP188 | c.1092C>T p.S364= | Silent (SNP) | VAF 45/130 reads (35%) | catalogued as COSV101001473; called by muse, mutect2, varscan2
- OCM | c.288G>A p.G96= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs1280452940, COSV99631503; called by muse, mutect2, varscan2
- OR13C8 | c.84C>T p.F28= | Silent (SNP) | VAF 41/137 reads (30%) | catalogued as rs759154891, COSV58611602, COSV58612415; called by muse, mutect2, varscan2
- OR1A1 | c.816C>T p.I272= | Silent (SNP) | VAF 43/156 reads (28%) | catalogued as COSV100410820; called by muse, mutect2, varscan2
- OR1B1 | c.384C>T p.I128= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV100506532; called by muse, mutect2, varscan2
- OR2A25 | c.156C>T p.S52= | Silent (SNP) | VAF 47/101 reads (47%) | catalogued as COSV101376411; called by muse, mutect2, varscan2
- OR2T6 | c.681G>A p.Q227= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV100861554, COSV63215784, COSV63216173; called by muse, mutect2, varscan2
- OR3A1 | c.99C>T p.L33= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as COSV100041815; called by muse, mutect2, varscan2
- OR4Q3 | c.687C>T p.I229= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as COSV59177386; called by muse, mutect2, varscan2
- OR4Q3 | c.777C>T p.I259= | Silent (SNP) | VAF 29/181 reads (16%) | catalogued as COSV100057300; called by muse, mutect2, varscan2
- OR51L1 | c.756C>T p.I252= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100386474; called by muse, mutect2
- OR52E4 | c.819C>T p.I273= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs267603036, COSV100389345; called by muse, mutect2, varscan2
- OR5D18 | c.189C>T p.F63= | Silent (SNP) | VAF 55/166 reads (33%) | catalogued as rs145410438, COSV61736632; called by muse, mutect2, varscan2
- OTOF | c.1866C>T p.I622= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs762720965, COSV99718703; called by muse, mutect2, varscan2
- OTOGL | c.6834G>A p.R2278= (on ENST00000547103; = p.R2269= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs1164508853, COSV54022955; called by muse, mutect2, varscan2
- OTULIN | c.312G>A p.T104= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs376880523, COSV52506976; called by muse, mutect2, varscan2
- PDLIM2 | c.288C>T p.S96= (on ENST00000397760; = p.S346= on NM_021630.6) | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV99747872; called by muse, mutect2, varscan2
- PGBD1 | c.672C>T p.A224= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV99460810; called by muse, mutect2, varscan2
- PGC | c.1101C>T p.F367= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV100026419; called by muse, mutect2, varscan2
- PHKA1 | c.684C>T p.I228= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV100263792; called by muse, mutect2, varscan2
- PIGQ | c.672A>G p.S224= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99216442; called by muse, mutect2, varscan2
- PKP2 | c.597C>T p.I199= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs866985131, COSV50727106, COSV50728255; called by muse, mutect2, varscan2
- PLEK | c.333G>A p.R111= | Silent (SNP) | VAF 47/166 reads (28%) | catalogued as rs1333245905, COSV52253367, COSV52253719; called by muse, mutect2, varscan2
- PLEKHG1 | c.2595G>A p.K865= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV100651831; called by muse, mutect2, varscan2
- PLIN5 | c.675C>T p.H225= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs1225349386, COSV101113655; called by muse, mutect2, varscan2
- PRAMEF12 | c.513G>A p.Q171= | Silent (SNP) | VAF 33/124 reads (27%) | catalogued as COSV100743557; called by muse, mutect2, varscan2
- PRR12 | c.3600C>T p.S1200= (on ENST00000615927; = p.S2021= on NM_020719.3) | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV101330778; called by muse, mutect2, varscan2
- RAB11FIP3 | c.2196C>T p.F732= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV99240766; called by muse, mutect2, varscan2
- RAB3D | c.615C>T p.A205= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs755507905, COSV99708939; called by muse, mutect2, varscan2
- REG1A | c.24C>T p.F8= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV52068337, COSV52068377; called by muse, mutect2, varscan2
- RFT1 | c.129C>T p.I43= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs148510042, COSV56248287, COSV56249820; called by muse, mutect2, varscan2
- RNF123 | c.3132C>T p.F1044= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as COSV100246719; called by muse, mutect2, varscan2
- RNF20 | c.1194G>A p.L398= | Silent (SNP) | VAF 58/183 reads (32%) | catalogued as COSV101206569; called by muse, mutect2, varscan2
- ROR2 | c.1659C>T p.F553= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV65223385; called by muse, mutect2, varscan2
- RTP3 | c.249G>A p.Q83= | Silent (SNP) | VAF 58/145 reads (40%) | catalogued as COSV99946976; called by muse, mutect2, varscan2
- RTP3 | c.339G>A p.R113= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as COSV99946912; called by muse, mutect2, varscan2
- RYR2 | c.2235C>T p.N745= | Silent (SNP) | VAF 71/278 reads (26%) | catalogued as COSV100772296; called by muse, mutect2, varscan2
- SALL2 | c.507C>T p.P169= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs1292785109, COSV58103150; called by muse, mutect2, varscan2
- SCUBE3 | c.282G>A p.R94= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV99235096; called by muse, mutect2, varscan2
- SDK2 | c.4590C>T p.I1530= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV101168367; called by muse, mutect2, varscan2
- SEMA3E | c.1923C>T p.F641= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as COSV57090640; called by muse, mutect2, varscan2
- SLC15A1 | c.1500C>T p.I500= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100919531; called by muse, mutect2, varscan2
- SLC4A4 | c.1504T>C p.L502= (on ENST00000264485 / NM_001098484.3; = p.L458= on NM_003759.4) | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as rs1214156669, COSV99141704; called by muse, mutect2, varscan2
- SLC5A9 | c.204C>T p.F68= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV52581892; called by muse, mutect2, varscan2
- SLC6A12 | c.1659C>T p.F553= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as rs138858909, COSV100675007; called by muse, mutect2, varscan2
- SNRNP200 | c.3855C>T p.S1285= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV60489243; called by muse, mutect2, varscan2
- SNTB1 | c.1221G>A p.G407= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as COSV101180089; called by muse, varscan2
- SORL1 | c.5103G>A p.Q1701= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99495165; called by muse, mutect2, varscan2
- SPATA31D1 | c.279G>A p.R93= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs774672809, COSV61193872, COSV61193944; called by muse, mutect2
- SPINT4 | c.270C>T p.A90= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV99651040; called by muse, mutect2, varscan2
- SULT1A1 | c.228C>T p.F76= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV59090568; called by muse, mutect2, varscan2
- SUPT5H | c.600C>T p.F200= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs1284160920, COSV100782139; called by muse, mutect2, varscan2
- TDRD10 | c.168C>T p.D56= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100873189; called by muse, mutect2, varscan2
- TDRD6 | c.666C>T p.S222= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs769804292, COSV60179001; called by muse, mutect2
- TEF | c.483C>T p.S161= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as rs1376078034, COSV99842023; called by muse, mutect2, varscan2
- TEKT5 | c.231C>T p.I77= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as COSV99296349; called by muse, mutect2, varscan2
- TENM2 | c.2904C>T p.F968= (on ENST00000518659 / NM_001122679.2; = p.F736= on NM_001080428.3) | Silent (SNP) | VAF 108/169 reads (64%) | catalogued as rs769209829, COSV69142786; called by muse, mutect2, varscan2
- TET3 | c.4185C>T p.S1395= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV101327876, COSV101328063; called by muse, mutect2, varscan2
- THSD7A | c.3982C>T p.L1328= | Silent (SNP) | VAF 21/35 reads (60%) | catalogued as rs769972708, COSV101439788; called by muse, mutect2, varscan2
- TIPARP | c.411C>T p.I137= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV55813724, COSV99903957; called by muse, mutect2, varscan2
- TLL2 | c.765C>T p.T255= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV100780451; called by muse, mutect2, varscan2
- TMEM182 | c.387C>T p.I129= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs780466991, COSV68424549; called by muse, mutect2, varscan2
- TMEM51 | c.675C>T p.V225= | Silent (SNP) | VAF 46/127 reads (36%) | catalogued as COSV101051572; called by muse, mutect2, varscan2
- TMEM74 | c.666G>A p.A222= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs745445272, COSV52463222; called by muse, mutect2, varscan2
- TNXB | c.7434G>A p.G2478= (on ENST00000647633; = p.G2231= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV64489698; called by muse, mutect2, varscan2
- TP53BP2 | c.2637A>C p.P879= (on ENST00000343537 / NM_001031685.3; = p.P750= on NM_005426.2) | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV100636761; called by muse, mutect2, varscan2
- TRAF1 | c.618G>A p.K206= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100875201; called by muse, mutect2, varscan2
- TRPC6 | c.1038G>A p.L346= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as COSV100723743; called by muse, mutect2, varscan2
- TSSC4 | c.789C>T p.P263= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs2234282; called by muse, mutect2, varscan2
- TTBK1 | c.3519C>A p.P1173= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV52487753, COSV99445420; called by muse, mutect2, varscan2
- TTC21A | c.1836C>T p.F612= | Silent (SNP) | VAF 40/129 reads (31%) | catalogued as rs777246055, COSV57188239; called by muse, mutect2, varscan2
- TTC27 | c.1566C>T p.S522= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV100513473; called by muse, mutect2, varscan2
- TTN | c.16734C>T p.F5578= (on ENST00000591111; = p.F4651= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 83/222 reads (37%) | catalogued as rs745855082, COSV100626235; called by muse, mutect2, varscan2
- TTN | c.318C>T p.F106= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs1219102157, COSV59863189; called by muse, mutect2, varscan2
- TXNDC2 | c.1176C>T p.S392= (on ENST00000306084 / NM_001098529.2; = p.S325= on NM_032243.6) | Silent (SNP) | VAF 37/121 reads (31%) | catalogued as COSV60154190; called by muse, mutect2, varscan2
- VAT1L | c.762C>T p.L254= | Silent (SNP) | VAF 37/73 reads (51%) | catalogued as COSV100213607; called by muse, mutect2, varscan2
- VBP1 | c.471C>T p.S157= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs914036498, COSV53972279; called by muse, mutect2, varscan2
- VIPAS39 | c.495G>A p.R165= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV100492847; called by muse, mutect2, varscan2
- VWF | c.6093T>G p.V2031= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV99779943; called by muse, mutect2, varscan2
- XCR1 | c.639C>T p.F213= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV58570187; called by muse, mutect2, varscan2
- XYLB | c.438C>T p.C146= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV99264453; called by muse, mutect2, varscan2
- ZC3H13 | c.1467C>T p.T489= | Silent (SNP) | VAF 42/141 reads (30%) | catalogued as rs764524512, COSV99668770; called by muse, mutect2, varscan2
- ZGPAT | c.673C>T p.L225= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100203265; called by muse, mutect2, varscan2
- ZNF107 | c.1767T>C p.F589= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV100788481; called by muse, mutect2, varscan2
- ZNF182 | c.831C>T p.L277= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV100527172; called by muse, mutect2, varscan2
- ZNF484 | c.1095C>T p.L365= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV60259177; called by muse, mutect2, varscan2
- ZNF605 | c.453C>T p.S151= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs948156126; called by muse, mutect2, varscan2
- ZRANB2 | c.804C>T p.S268= | Silent (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2
- ZSWIM3 | c.432C>T p.S144= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV54848079; called by muse, mutect2, varscan2
- CCDC144NL | n.681G>A | RNA (SNP) | VAF 5/11 reads (45%) | catalogued as COSV100019502; called by muse, mutect2, varscan2
- CCNQP1 | n.640C>T | RNA (SNP) | VAF 38/94 reads (40%) | catalogued as rs1312978429; called by muse, mutect2, varscan2
- DCHS2 | n.519C>T | RNA (SNP) | VAF 10/36 reads (28%) | catalogued as rs186939809, COSV100252898; called by muse, mutect2, varscan2
- GPX4 | c.85-339G>A | Intron (SNP) | VAF 6/18 reads (33%) | catalogued as COSV62321149; called by muse, mutect2, varscan2
- LEPR | c.2673+3162A>G | Intron (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100756727; called by muse, mutect2, varscan2
- MAGEA5 | n.225C>T | RNA (SNP) | VAF 35/123 reads (28%) | catalogued as rs778167841; called by muse, mutect2, varscan2
- NBPF7 | n.841G>A | RNA (SNP) | VAF 18/62 reads (29%) | catalogued as rs760398333; called by muse, mutect2, varscan2
- PLCXD2 | c.*56C>T | 3'UTR (SNP) | VAF 13/63 reads (21%) | catalogued as rs748544895, COSV101208353; called by muse, mutect2, varscan2
- PNCK | c.539-74G>A | Intron (SNP) | VAF 34/99 reads (34%) | catalogued as rs1557039804, COSV100562448, COSV61743101; called by muse, mutect2, varscan2
- PTN | c.-178T>C | 5'UTR (SNP) | VAF 24/48 reads (50%) | catalogued as COSV100780998; called by muse, mutect2, varscan2
- SSPOP | n.8012G>A | RNA (SNP) | VAF 12/15 reads (80%) | catalogued as COSV100947927; called by muse, mutect2, varscan2
- TTN | c.10361-4157G>A | Intron (SNP) | VAF 35/121 reads (29%) | catalogued as rs776175211, COSV59936795; called by muse, mutect2, varscan2
